Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4845, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4845-01A (Primary Tumor).

FINAL DIAGNOSIS

TCGA-B0-4845

PART 1:

RIGHT KIDNEY, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN'S NUCLEAR GRADE 2 OF 4, 5.5 cm IN GREATEST DIMENSION.
- B. MICROSCOPIC PERINEPHRIC ADIPOSE TISSUE INVOLVEMENT IS PRESENT.
- C. ALL SURGICAL MARGINS (URETERAL, VASCULAR, RADIAL) ARE NEGATIVE FOR NEOPLASIA.
- D. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- E. NON-NEOPLASTIC RENAL PARENCHYMA SHOWS NO SIGNIFICANT PATHOLOGIC FEATURES.
- F. PATHOLOGIC TNM STAGE: pT3a Nx Mx.

PART 2:

RIGHT ADRENAL GLAND, COMPLETION OF RADICAL NEPHRECTOMY -
ADRENAL GLAND WITH NO SIGNIFICANT PATHOLOGIC FINDINGS.

Source: NCI Genomic Data Commons file cc852e51-7ed1-40a0-aa7b-2a3bfb1b7e5e (TCGA-B0-4845.A6ED168A-DB1A-4AC6-9979-3560EFE5DAAA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).